Somatic mutation profile of tumor specimen ALCH-ADC3-TTP1-A (aliquot ALCH-ADC3-TTP1-A-1-0-D-A581-36) from ALCHEMIST case ALCH-ADC3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,209 days).
Specimen ALCH-ADC3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c27ba3b-d4b7-4dcd-bbeb-95a4826c236d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADC3-NB1-A (Blood Derived Normal), aliquot ALCH-ADC3-NB1-A-1-0-D-A581-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d18b4b9f-5d0a-4f42-af2e-28162b78f952

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 2, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 90/984 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2
- FLG | c.10078C>T p.Q3360* | Nonsense Mutation (SNP) | VAF 33/841 reads (4%) | catalogued as rs1266395447, COSV100910346; called by muse, mutect2
- NCAM2 | c.649T>A p.S217T | Missense Mutation (SNP) | VAF 15/370 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.433); catalogued as COSV53097151; called by muse, mutect2
- PICK1 | c.834+5G>A | Splice Region (SNP) | VAF 33/382 reads (9%) | catalogued as rs1182414059; called by muse, mutect2
- PXDC1 | c.542G>A p.R181K | Missense Mutation (SNP) | VAF 37/540 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1370946417; called by muse, mutect2
- WDFY1 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 21/667 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1472277300; called by muse, mutect2
- BMP7 | c.1114A>G p.N372D | Missense Mutation (SNP) | VAF 88/556 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MYH15 | c.3595A>T p.T1199S | Missense Mutation (SNP) | VAF 16/449 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- MYO9A | c.6235G>A p.V2079M | Missense Mutation (SNP) | VAF 16/504 reads (3%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.828); called by muse, mutect2
- RALGAPA2 | c.3562G>C p.V1188L | Missense Mutation (SNP) | VAF 26/812 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.638); called by muse, mutect2
- RBM10 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- SECISBP2L | c.1467G>T p.Q489H (on ENST00000559471 / NM_001193489.2; = p.Q444H on NM_014701.4) | Missense Mutation (SNP) | VAF 19/400 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2
- SEZ6 | c.1972G>A p.V658I | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- SLC35F5 | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 20/293 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2
- CREB3L4 | c.627C>T p.P209= | Silent (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2, varscan2
- UBA1 | c.831C>A p.I277= | Silent (SNP) | VAF 24/698 reads (3%) | called by muse, mutect2
